FM case AD14039 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/b6875b1f-8a68-4494-9a98-4dc53dba5f74

Female, 54.4 years: Carcinoma, NOS (ICD-O-3 8010/3) of the kidney; metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
